Somatic mutation profile of tumor specimen 0DML9U from CCDI case PBCAKK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 20.3 years (7,398 days).
Specimen 0DML9U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f7e8566-979f-4684-bb6b-1c52df88c077.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DML9N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c8dfc86-8fd1-4daa-a81a-a382bde93dd2

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Intron 3, RNA 2, 3'UTR 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIC6 | c.2109G>A p.M703I (on ENST00000360731 / NM_001317009.2; = p.M685I on NM_053277.3) | Missense Mutation (SNP) | VAF 64/1476 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1405536479, COSV62447384, COSV62449978; called by muse, mutect2
- FSTL1 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 42/1318 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1264771002; called by muse, mutect2
- GLYR1 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 150/1222 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs757745527; called by muse, mutect2, varscan2
- KCNQ4 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 319/927 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1301376340, COSV100714356; called by muse, mutect2, varscan2
- LRRC4B | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.006); catalogued as rs777753674, COSV65349602; called by muse, mutect2, varscan2
- NCDN | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 339/990 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs746183935, COSV61934904; called by muse, mutect2, varscan2
- NLRP5 | c.1454A>G p.D485G | Missense Mutation (SNP) | VAF 36/700 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101173775; called by muse, mutect2
- PHGDH | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 302/818 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs773221019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R1 | c.1363C>A p.Q455K (on ENST00000521381 / NM_181523.3; = p.Q185K on NM_181504.4) | Missense Mutation (SNP) | VAF 49/965 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV57131875; called by muse, mutect2
- RAB8A | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 201/601 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56292999; called by muse, mutect2, varscan2
- RYR3 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 331/1030 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs757881583, COSV101212070; called by muse, mutect2, varscan2
- ZBED5 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 462/889 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV101302688; called by muse, mutect2, varscan2
- ZNF836 | c.2231A>G p.H744R | Missense Mutation (SNP) | VAF 263/714 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1253187382; called by muse, mutect2, varscan2
- ATXN7L1 | c.1141G>C p.G381R | Missense Mutation (SNP) | VAF 215/1688 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- C16orf78 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 368/1041 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CCL18 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 82/959 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.41); called by muse, mutect2
- DENND4C | c.2363C>G p.A788G | Missense Mutation (SNP) | VAF 30/1216 reads (2%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2
- DLGAP3 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 476/2126 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIA3 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 24/830 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HYDIN | c.13681T>G p.F4561V | Missense Mutation (SNP) | VAF 147/461 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGSF10 | c.2648A>G p.Q883R | Missense Mutation (SNP) | VAF 639/1856 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP28 | c.1093A>T p.R365* | Nonsense Mutation (SNP) | VAF 438/809 reads (54%) | called by muse, mutect2, varscan2
- NOVA2 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 125/389 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PCDHGA2 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 429/713 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM15B | c.1670C>G p.S557C | Missense Mutation (SNP) | VAF 79/976 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, mutect2
- RPS6KC1 | c.1871T>C p.L624P | Missense Mutation (SNP) | VAF 511/1541 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SEPTIN3 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 37/1520 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SF3B3 | c.1825C>A p.L609I | Missense Mutation (SNP) | VAF 41/1549 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, mutect2
- SOX4 | c.320del p.P107Lfs*28 | Frame Shift Del (DEL) | VAF 253/875 reads (29%) | called by mutect2, pindel, varscan2
- THSD7A | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 40/1510 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2
- TLN1 | c.1961A>G p.Q654R | Missense Mutation (SNP) | VAF 30/1142 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- TMX4 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 32/1104 reads (3%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- TSR1 | c.2267A>T p.D756V | Missense Mutation (SNP) | VAF 200/1409 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VCAN | c.1411A>G p.T471A | Missense Mutation (SNP) | VAF 428/1150 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CLCNKA | c.1728G>T p.V576= | Silent (SNP) | VAF 231/744 reads (31%) | called by muse, mutect2, varscan2
- FOXD4L5 | c.954G>A p.R318= | Silent (SNP) | VAF 172/1346 reads (13%) | called by muse, mutect2, varscan2
- GFOD2 | c.735C>T p.G245= | Silent (SNP) | VAF 235/700 reads (34%) | catalogued as rs756593534, COSV52059321; called by muse, mutect2, varscan2
- H1-4 | c.588C>G p.P196= | Silent (SNP) | VAF 393/1128 reads (35%) | catalogued as COSV56800188; called by muse, mutect2, varscan2
- NCDN | c.1731C>T p.A577= | Silent (SNP) | VAF 422/1257 reads (34%) | catalogued as rs1184225678; called by muse, mutect2, varscan2
- NRDC | c.1746T>C p.G582= | Silent (SNP) | VAF 34/1306 reads (3%) | catalogued as COSV61405119; called by muse, mutect2
- NUP88 | c.1480T>C p.L494= | Silent (SNP) | VAF 205/644 reads (32%) | called by muse, mutect2, varscan2
- ODF2L | c.1485C>T p.D495= (on ENST00000317336; = p.D466= on NM_020729.3) | Silent (SNP) | VAF 226/1202 reads (19%) | called by muse, mutect2, varscan2
- PCED1B | c.1215C>A p.P405= | Silent (SNP) | VAF 255/894 reads (29%) | catalogued as COSV71395240; called by muse, mutect2, varscan2
- TTBK1 | c.63C>G p.A21= | Silent (SNP) | VAF 72/725 reads (10%) | called by muse, mutect2, varscan2
- C2CD2L | c.1387+60G>C | Intron (SNP) | VAF 130/243 reads (53%) | called by muse, mutect2, varscan2
- DNMT1 | c.879-72C>T | Intron (SNP) | VAF 132/420 reads (31%) | called by muse, mutect2, varscan2
- LINC02843 | n.263G>A | RNA (SNP) | VAF 365/583 reads (63%) | called by muse, mutect2, varscan2
- MUC19 | n.20536A>G | RNA (SNP) | VAF 224/764 reads (29%) | called by muse, mutect2, varscan2
- PTGS1 | c.*36_*42del | 3'UTR (DEL) | VAF 212/406 reads (52%) | called by mutect2, pindel, varscan2
- SCAMP2 | c.225+587A>C | Intron (SNP) | VAF 61/2126 reads (3%) | called by muse, mutect2
- ZFPM1 | c.*49G>T | 3'UTR (SNP) | VAF 82/250 reads (33%) | called by muse, mutect2, varscan2
